Surgical pathology report (de-identified scan), TCGA case TCGA-DJ-A2PO, project TCGA-THCA (Thyroid Carcinoma), tissue source site Memorial Sloan Kettering, specimen TCGA-DJ-A2PO-01A (Primary Tumor).

[page 1 of 4]
fw 8/31/11		

Date of Procedure:

Date of Receipt:

Date of Report:

Account #:

Billing Type:

INPATIENT

Additional Copy to:

Ref. Source:

Clinical Diagnosis & History:

Bilateral thyroid nodule left nodule FNA positive papillary thyroid cancer.

Specimens Submitted:

- 1: Left paratracheal lymph node, excision (fs)
- 2: Rule out left lower parathyroid (fs)
- 3: Left paratracheal lymph node # 2, excision (fs)
- 4: Additional left paratracheal tissue, excision
- 5: Delphian node, excision
- 6: Thyroid, total thyroidectomy

UUID: 752F974A-53AA-4946-9994-E4E49EEESAEC

DIAGNOSIS:

1. Left paratracheal lymph node, excision (fs):
Lymph Node Dissection:
Benign lymph nodes
Number of lymph nodes examined: 2
2. Parathyroid, left lower, excision (fs):
- Fragment of benign unremarkable parathyroid gland
3. Left paratracheal lymph node # 2, excision (fs):
Lymph Node Dissection:
Benign lymph nodes
Number of lymph nodes examined: 1
4. Additional left paratracheal tissue, excision:
Lymph Node Dissection:
Benign fibroadipose tissue
5. Delphian node, excision:
Lymph Node Dissection:
Benign lymph nodes
Number of lymph nodes examined: 1
6. Thyroid, total thyroidectomy:
Tumor Type:
Two foci of papillary microcarcinoma

Histologic Grade:
Well differentiated

ICB-0-3

Carcinoma, papillary, Thyroid 8260/3

Site: Thyroid, NOS C73.9

fw
8/31/11

fw

[page 2 of 4]
Mitotic Activity:

Not identified

Tumor Necrosis:

Not identified

Tumor Location:

Left lobe

Right lobe

Tumor Size:

6 mm in left lobe and 2 mm in right lobe

Blood Vessel Invasion:

Not identified

Extrathyroid Extension:

Not identified

Surgical Margins:

Free of tumor

Tumor Multicentricity:

Microscopic foci present

Non-Neoplastic Thyroid:

Exhibits chronic lymphocytic thyroiditis

Parathyroid Glands:

Not identified

Lymph Nodes:

One benign lymph node is identified

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

*** Report Electronically Signed Out ***

Gross Description:

1. The specimen is received fresh, labeled "left paratracheal lymph node". It consists of two pieces of tan pink soft tissue measuring 0.3 and 0.6 cm in greatest dimension. The specimen is submitted entirely for frozen section.

Summary of Sections:

FSC- frozen section control

2. The specimen is received fresh, labeled "Rule out left lower parathyroid ". It consists of tan soft tissue measuring 0.3 x 0.3 x 0.2 cm. The specimen is submitted entirely for frozen section.

Summary of Sections:

FSC- frozen section control

3. The specimen is received fresh, labeled "left paratracheal lymph node #2". It consists of tan soft tissue measuring 0.7 x 0.4 x 0.3 cm. The specimen is submitted entirely for frozen section.

[page 3 of 4]
Summary of Sections:
FSC- frozen section control

4). The specimen is received which fresh, labeled "Additional left paratracheal tissue" and consists of a 1.3 x 1.1 x 0.3 cm fragment of tan soft tissue. Entirely submitted.

Summary of sections:
U - undesignated

5). The specimen is received fresh, labeled "Delphian node" and consists of a single lymph node measuring 0.9 x 0.7 x 0.3 cm. The lymph node is entirely submitted.

Summary of sections:
U - lymph node

6). The specimen is received fresh, labeled "total thyroid stitch marks left lobe" and consists of a thyroid weighing 20.5 g. The right lobe measures 4.6 x 2.5 x 1.3 cm, the left lobe measures 3.2 x 2.8 x 1.4 cm and the isthmus measures 2.6 x 1.5 x 0.8 cm. The external surface is covered by a thin fibrous capsule. The posterior surface of the specimen is inked black, and the anterior is inked blue. Sectioning reveals a well-circumscribed tan-yellow firm nodule measuring 0.6 x 0.6 x 0.6 cm, in the left mid to upper lobe. Sections through the remaining tissue reveal faint tan-white papillary foci in the right lobe but otherwise unremarkable. The remaining thyroid parenchyma is red tan and beefy. Representative sections of the specimen are submitted for TPS. The remaining tissue is serially sectioned and representatively submitted.

Summary of sections:
LN - left lobe the nodule
RL - right lobe
LL - left lobe
IS - isthmus

Summary of Sections:

Part 1: Left paratracheal lymph node, excision (fs)

Block	Sect. Site	PCs
1	FSC	1

Part 2: Rule out left lower parathyroid (fs)

Block	Sect. Site	PCs
1	FSC	1

Part 3: Left paratracheal lymph node # 2, excision (fs)

Block	Sect. Site	PCs
1	FSC	1

Part 4: Additional left paratracheal tissue, excision

Block	Sect. Site	PCs
1	U	1

Part 5: Delphian node, excision

Block	Sect. Site	PCs
1	U	1

Part 6: Thyroid, total thyroidectomy

[page 4 of 4]
Block	Sect. Site	PCs
1	IS	1
3	LL	3
2	LN	2
3	RL	3

Intraoperative Consultation:

Note: The diagnoses given in this section pertain only to the tissue sample examined at the time of the intraoperative consultation.

1. Frozen section diagnosis: left paratracheal lymph node (fs): benign lymph node
Permanent diagnosis: same
2. Frozen section diagnosis: rule out left lower parathyroid (fs): parathyroid tissue
Permanent diagnosis: same
3. Frozen section diagnosis: left paratracheal lymph node # 2 (fs): benign lymph node
Permanent diagnosis:

Source: NCI Genomic Data Commons file 4bcbb096-ddf4-4b74-bae1-9c6f2a6c65f6 (TCGA-DJ-A2PO.752F974A-53AA-4946-9994-E4E49EEE5AEC.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).